Somatic mutation profile of tumor specimen 0DUVTU from CCDI case PBCLIW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 3.9 years (1,433 days).
Specimen 0DUVTU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b1d7fe6b-f846-476c-9008-12d9d008c3b0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUVT1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4deaaaae-ac94-4912-8fa7-7222bcfe6c2f

The open-access MAF lists 32 somatic variants for this specimen: 20 protein-altering or splice-affecting, 6 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 6, Intron 3, 5'UTR 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR4 | c.1648G>A p.V550M | Missense Mutation (SNP) | VAF 163/360 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774571806, COSV52800715, COSV52802492, COSV52804538; called by muse, mutect2, varscan2
- ALDH4A1 | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 163/543 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs142969512, COSV51893094; called by muse, mutect2, varscan2
- CLK2 | c.1457C>T p.P486L (on ENST00000368361 / NM_001294339.2; = p.P485L on NM_003993.4) | Missense Mutation (SNP) | VAF 168/622 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs768060382; called by muse, mutect2, varscan2
- CSMD1 | c.2950T>C p.Y984H (on ENST00000520002; = p.Y983H on NM_033225.6) | Missense Mutation (SNP) | VAF 92/2472 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.541); catalogued as rs1367888813; called by muse, mutect2
- CSMD2 | c.8537G>A p.R2846H | Missense Mutation (SNP) | VAF 64/742 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.513); catalogued as rs775463572, COSV53879418; called by muse, mutect2
- DNAH6 | c.9421A>G p.K3141E | Missense Mutation (SNP) | VAF 76/1120 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs932767025; called by muse, mutect2
- MAOB | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 36/704 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as rs980435225, COSV100955858, COSV100956289; called by muse, mutect2
- PIK3CB | c.1162G>C p.D388H | Missense Mutation (SNP) | VAF 243/791 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56691631; called by muse, mutect2, varscan2
- SMARCA4 | c.887C>T p.T296M | Missense Mutation (SNP) | VAF 93/342 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.212); catalogued as rs781066262; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TMC5 | c.2077G>A p.V693I (on ENST00000396229 / NM_001105248.1; = p.V447I on NM_024780.5) | Missense Mutation (SNP) | VAF 127/436 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs201085859; called by muse, mutect2, varscan2
- TMEM259 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 75/259 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs202085162; called by muse, mutect2, varscan2
- CD46 | c.1164A>T p.K388N | Missense Mutation (SNP) | VAF 32/980 reads (3%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.007); called by muse, mutect2
- EPPK1 | c.3399G>C p.Q1133H | Missense Mutation (SNP) | VAF 23/604 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); called by muse, mutect2
- MED12 | c.3182T>A p.V1061D | Missense Mutation (SNP) | VAF 104/460 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- MFSD12 | c.959T>C p.M320T | Missense Mutation (SNP) | VAF 43/276 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.261); called by mutect2, varscan2
- NEURL4 | c.4205G>A p.R1402K | Missense Mutation (SNP) | VAF 124/522 reads (24%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- PABPC3 | c.362C>A p.A121D | Missense Mutation (SNP) | VAF 164/886 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, varscan2
- PCDHB8 | c.2156G>C p.R719T | Missense Mutation (SNP) | VAF 59/237 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- TCP11X2 | c.905A>T p.D302V | Missense Mutation (SNP) | VAF 224/1662 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ZNF316 | c.2239T>A p.F747I | Missense Mutation (SNP) | VAF 16/328 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); called by muse, mutect2
- ARAP2 | c.2169T>C p.C723= | Silent (SNP) | VAF 41/388 reads (11%) | called by muse, mutect2, varscan2
- ATG9B | c.1140C>T p.R380= | Silent (SNP) | VAF 62/226 reads (27%) | called by muse, mutect2, varscan2
- CTXN2 | c.48C>T p.N16= | Silent (SNP) | VAF 199/734 reads (27%) | catalogued as rs1233263807, COSV66796467; called by muse, mutect2, varscan2
- HMCN1 | c.10107G>A p.T3369= | Silent (SNP) | VAF 247/747 reads (33%) | catalogued as rs766008429, COSV54888352; called by muse, mutect2, varscan2
- MAP3K11 | c.783G>A p.K261= | Silent (SNP) | VAF 81/659 reads (12%) | called by muse, mutect2, varscan2
- RAPGEF2 | c.1638A>T p.P546= | Silent (SNP) | VAF 28/517 reads (5%) | called by muse, mutect2
- BDH2 | c.419-36A>G | Intron (SNP) | VAF 23/87 reads (26%) | called by muse, mutect2, varscan2
- CLIC5 | c.*96G>A | 3'UTR (SNP) | VAF 22/92 reads (24%) | catalogued as rs957805647, COSV99484236, COSV99485563; called by muse, mutect2, varscan2
- ECE1 | c.-181C>A | 5'UTR (SNP) | VAF 5/44 reads (11%) | catalogued as rs995822798; called by muse, mutect2, varscan2
- EFEMP2 | c.1170+57G>T | Intron (SNP) | VAF 35/243 reads (14%) | called by muse, mutect2, varscan2
- LRRC18 | c.-43C>G | 5'UTR (SNP) | VAF 33/112 reads (29%) | called by muse, mutect2, varscan2
- RALGAPA1 | c.2434+171G>C | Intron (SNP) | VAF 203/801 reads (25%) | called by muse, mutect2, varscan2
